Gene-level copy-number profile of tumor specimen TCGA-2Y-A9HA-01A from TCGA case TCGA-2Y-A9HA, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 70.9 years (25,892 days).
Specimen TCGA-2Y-A9HA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.ff6be172-8b76-4f1d-9ab8-df7f05b8e9a1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Y-A9HA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6b184ed9-8e25-4fda-a4e5-5b84e16e1cc6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 58; copy number 2: 10,719; copy number 3: 3,880; copy number 4: 34,607; copy number 5: 7,114; copy number 6: 668; copy number 7: 625; copy number 8: 213; copy number 9: 1,700; copy number 13: 4; copy number 14: 1; copy number 15: 24; copy number 16: 10; copy number 17: 97; copy number 19: 2; copy number 22: 18; copy number 23: 26; copy number 24: 9; copy number 26: 6; copy number 27: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Y-A9HA-01A-11D-A38W-01): tumor purity 0.79, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:78,981,722–79,211,264, 8 genes: AC027279.3, AC027279.2, AC009145.4, AC009145.3, AC009145.1, AC009145.2, AC092376.2, AC092376.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,918 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,510,510–161,964,070, 535 genes, copy number 9–26 (broad region; genes not listed).
- chr1:162,069,691–162,370,475, 1 gene, copy number 17 (within-gene range 2–17): NOS1AP.
- chr1:162,316,852–163,509,595, 29 genes, copy number 17–24: AL512785.1, RNA5SP61, MIR556, AL512785.2, SPATA46, C1orf226, SH2D1B, SLAMF6P1, UHMK1, UQCRBP2, AL596325.1, UAP1, AL596325.2, DDR2, RN7SL861P, HSD17B7, CCDC190, AL392003.2, AL392003.1, RGS4, RGS5, RGS5-AS1, AL451063.1, RGS5, AL592435.1, NUF2, AL603841.1, RNA5SP62, RNA5SP63.
- chr1:181,668,749–182,090,112, 9 genes, copy number 16: Metazoa_SRP, RNA5SP70, AL161734.2, AL161734.1, RN7SKP229, AL391477.1, ZNF648, AL355482.1, AL355482.2.
- chr1:182,127,297–182,128,682, 1 gene, copy number 16: AL390856.1.
- chr1:184,387,029–184,629,019, 1 gene, copy number 22 (within-gene range 2–22): C1orf21.
- chr1:184,566,511–184,754,907, 4 genes, copy number 22: AL078645.2, AL713852.1, AL713852.2, EDEM3.
- chr1:184,821,428–184,821,489, 1 gene, copy number 22: RNU7-13P.
- chr1:185,157,080–185,291,781, 1 gene, copy number 27 (within-gene range 2–27): SWT1.
- chr1:185,226,808–185,520,986, 13 genes, copy number 27: RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2.
- chr1:191,823,432–193,365,953, 26 genes, copy number 23 (within-gene range 1–23): LINC02770, AL359081.1, RGS18, AL390957.1, AL513175.1, AL513175.2, RGS21, AL136987.1, RGS1, RGS13, RPS27AP5, MIR4426, AL035407.2, AL035407.1, RGS2, RN7SKP126, ZNF101P2, UCHL5, SCARNA18B, RO60, GLRX2, CDC73, MIR1278, B3GALT2, Metazoa_SRP, LINC01031.
- chr1:198,156,994–198,322,420, 1 gene, copy number 27 (within-gene range 2–27): NEK7.
- chr1:198,450,666–198,757,476, 6 genes, copy number 27: AL450352.1, ATP6V1G3, AL157402.1, PTPRC, AL157402.2, PEBP1P3.
- chr1:199,148,598–200,177,420, 12 genes, copy number 22 (within-gene range 2–22): LINC02789, RPL23AP16, AC099335.1, AL596266.1, AL445687.1, RNU6-778P, AL445687.2, RNU6-716P, RNU6-609P, NR5A2, RNU6-570P, AC096633.1.
- chr1:202,724,495–203,186,704, 24 genes, copy number 15: KDM5B, AC098934.1, SLC25A39P1, AC098934.2, PCAT6, MGAT4EP, TUBA5P, ACTG1P25, RABIF, KLHL12, HNRNPA1P59, Y_RNA, ADIPOR1, CYB5R1, MGAT4FP, AC096632.1, TMEM183A, PPFIA4, MYOG, ADORA1, AC105940.2, AC105940.1, MYBPH, CHI3L1.
- chr1:205,042,937–207,184,062, 78 genes, copy number 17 (broad region; genes not listed).
- chr6:95,504,182–95,632,929, 4 genes, copy number 13: CYCSP17, MANEA-DT, MANEA, AL607077.1.
- chr8:56,160,909–139,508,971, 1,171 genes, copy number 9 (broad region; genes not listed).
- chr22:47,662,559–47,663,603, 1 gene, copy number 14: AL117329.2.

Autosomal genes at a single copy (total copy number 1): 58. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
